Somatic mutation profile of tumor specimen TCGA-AD-6890-01A (aliquot TCGA-AD-6890-01A-11D-1924-10) from TCGA case TCGA-AD-6890, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; Age at diagnosis: 65.1 years (23,769 days).
Specimen TCGA-AD-6890-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a4af7cd-5593-421e-8be2-b5232033b976.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AD-6890-10A (Blood Derived Normal), aliquot TCGA-AD-6890-10A-01D-1924-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e9e67ca-a057-4bbf-9ca0-052323568de8

The open-access MAF lists 119 somatic variants for this specimen: 86 protein-altering or splice-affecting, 30 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 30, Nonsense Mutation 9, Frame Shift Del 4, Intron 2, Frame Shift Ins 2, In Frame Del 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2805C>A p.Y935* | Nonsense Mutation (SNP) | VAF 30/65 reads (46%) | hotspot (GDC flag); catalogued as rs137854575, CD041148, CM920044, CM970086, COSV57324059, COSV57328770; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 34/126 reads (27%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PAX3 | c.812G>A p.R271H | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs774528745, CM950907, COSV60588318; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 88/218 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- SOX9 | c.455_457del p.R152del | In Frame Del (DEL) | VAF 31/113 reads (27%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ACR | c.926C>T p.P309L | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.199); catalogued as rs770629027, COSV53361006; called by muse, mutect2, varscan2
- ADAMTS10 | c.1366C>T p.R456W | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs374908665, COSV54355234; called by muse, mutect2, varscan2
- ADCY8 | c.3581C>T p.A1194V | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.565); catalogued as rs773491638, COSV53897305, COSV53908386; called by muse, mutect2, varscan2
- ADGRG4 | c.5615C>A p.S1872Y | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV54955683, COSV99794114; called by muse, mutect2, varscan2
- AGBL1 | c.1232T>C p.V411A | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs372444093; called by muse, mutect2, varscan2
- AHNAK2 | c.14787G>T p.L4929F | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.415); catalogued as COSV60915019; called by muse, mutect2, varscan2
- AMER1 | c.1801C>T p.R601* | Nonsense Mutation (SNP) | VAF 15/23 reads (65%) | catalogued as COSV57659668; called by muse, mutect2, varscan2
- AQP10 | c.592A>G p.I198V | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV61474980; called by muse, mutect2, varscan2
- ASIC1 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs759280738, COSV57317834; called by muse, mutect2, varscan2
- ATP10A | c.1370G>A p.R457H | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as rs1161703668, COSV63517148; called by muse, mutect2, varscan2
- BCL9L | c.2038C>T p.R680W | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1315049646, COSV52688019; called by muse, mutect2
- BRINP3 | c.471C>A p.S157R | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV66523789, COSV66528036; called by muse, mutect2, varscan2
- C17orf58 | c.209T>C p.L70P | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV100558724; called by muse, mutect2
- CEP72 | c.1646C>T p.T549M | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.382); catalogued as rs577972731, COSV53792634; called by muse, mutect2, varscan2
- CNTN6 | c.2750C>G p.S917C | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs769171500, COSV63171708; called by muse, mutect2, varscan2
- CSMD2 | c.7357G>A p.A2453T | Missense Mutation (SNP) | VAF 57/169 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.376); catalogued as rs760040789, COSV99590102; called by muse, mutect2, varscan2
- DBT | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.599); catalogued as rs766629953, COSV100923508; called by muse, mutect2, varscan2
- EPRS1 | c.3070C>G p.L1024V | Missense Mutation (SNP) | VAF 106/177 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV65098813; called by muse, mutect2, varscan2
- FAT4 | c.13879G>A p.A4627T | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs746747643, COSV58710811; called by muse, mutect2, varscan2
- FBXL7 | c.1265G>A p.C422Y | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as COSV61645724, COSV61647666; called by muse, mutect2, varscan2
- GRIA1 | c.2711C>T p.T904M | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV53602346; called by muse, mutect2, varscan2
- GZF1 | c.722C>T p.T241M | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs756784368, COSV57636001; called by muse, mutect2, varscan2
- HELQ | c.1348G>T p.E450* | Nonsense Mutation (SNP) | VAF 41/192 reads (21%) | catalogued as COSV55025180; called by muse, mutect2, varscan2
- KCNA5 | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.028); catalogued as rs1205541618, COSV52905614; called by muse, mutect2, varscan2
- KCNT2 | c.3316C>A p.P1106T | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as COSV54078938; called by muse, mutect2, varscan2
- KDM7A | c.1317A>T p.L439F | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.78); PolyPhen probably damaging (0.997); catalogued as COSV50091416; called by muse, mutect2, varscan2
- KHNYN | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.655); catalogued as COSV52160431; called by muse, mutect2, varscan2
- KIAA1109 | c.5926G>A p.E1976K | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.971); catalogued as COSV52672418; called by muse, mutect2, varscan2
- KRT38 | c.1265C>T p.T422M | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); catalogued as rs146369884; called by muse, mutect2, varscan2
- MAGEL2 | c.3431G>A p.R1144Q | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); catalogued as rs756210530, COSV58567150; called by muse, mutect2, varscan2
- MAP2K7 | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1156815343, COSV67607577, COSV67607584; called by muse, mutect2, varscan2
- MSH6 | c.388C>A p.H130N | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99315982; called by muse, mutect2, varscan2
- MTCL1 | c.3340G>A p.G1114R (on ENST00000306329 / NM_001378206.1; = p.G795R on NM_015210.4) | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as COSV60405974; called by muse, mutect2, varscan2
- MUC16 | c.43319G>T p.R14440I | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.474); catalogued as COSV66691896; called by muse, mutect2, varscan2
- MYO6 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 66/155 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs573770611, COSV64117092; called by muse, mutect2, varscan2
- NLRP13 | c.2430C>A p.C810* | Nonsense Mutation (SNP) | VAF 16/47 reads (34%) | catalogued as rs907101620, COSV61621628; called by muse, mutect2, varscan2
- NLRX1 | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs754221240, COSV52703359, COSV52704332; called by muse, mutect2, varscan2
- NTF3 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as rs1343595285; called by muse, mutect2
- OCIAD1 | c.61A>G p.I21V | Missense Mutation (SNP) | VAF 39/183 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.191); catalogued as COSV51900724; called by muse, mutect2, varscan2
- OPA1 | c.2047G>T p.V683L (on ENST00000361510 / NM_130837.3; = p.V628L on NM_015560.3) | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.062); catalogued as COSV62480488; called by muse, mutect2, varscan2
- PCDHA2 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV65366617; called by muse, mutect2, varscan2
- PCDHGA11 | c.1807G>A p.A603T | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV53945315; called by muse, mutect2, varscan2
- PIWIL1 | c.1190G>A p.R397H | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); catalogued as rs1225500017, COSV55346646, COSV99807047; called by muse, mutect2, varscan2
- PWP1 | c.961G>A p.D321N | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69832777; called by muse, mutect2, varscan2
- PWWP3B | c.143T>A p.I48N | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV61799671; called by muse, mutect2, varscan2
- RERGL | c.436C>T p.R146* | Nonsense Mutation (SNP) | VAF 40/89 reads (45%) | catalogued as rs753937969, COSV57461923; called by muse, mutect2, varscan2
- RGL3 | c.1580C>T p.A527V | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.38); catalogued as rs372106275; called by muse, mutect2, varscan2
- RGS14 | c.153C>A p.S51R | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV68771216; called by muse, mutect2, varscan2
- RNF40 | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV61214627, COSV61214792; called by muse, mutect2, varscan2
- RP1L1 | c.1477C>T p.R493W | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs760566692, COSV66754807; called by muse, mutect2, varscan2
- SAMD8 | c.455C>T p.T152I | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.854); catalogued as COSV65509690; called by muse, mutect2, varscan2
- SDK1 | c.3992G>A p.R1331Q | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.453); catalogued as rs752248624, COSV67368205; called by muse, mutect2, varscan2
- SERTAD2 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs1184764516, COSV57640211; called by muse, mutect2, varscan2
- SEZ6L | c.1621C>T p.R541C | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.965); catalogued as rs758741564, COSV50659876; called by muse, varscan2
- SH3GL1 | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as rs150815092; called by mutect2, varscan2
- SHC4 | c.464C>A p.A155E | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.014); catalogued as COSV60112161; called by muse, mutect2, varscan2
- SLC44A3 | c.1332A>C p.L444F (on ENST00000271227 / NM_001114106.3; = p.L396F on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as COSV54730083; called by muse, mutect2, varscan2
- SLIT3 | c.1805G>A p.R602H | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.953); catalogued as rs374334394; called by muse, mutect2, varscan2
- SMC3 | c.1118C>T p.T373M | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs377731006; called by muse, mutect2, varscan2
- SNTB2 | c.1489C>T p.R497* | Nonsense Mutation (SNP) | VAF 24/85 reads (28%) | catalogued as COSV60349136; called by muse, mutect2, varscan2
- SYNE1 | c.14164G>A p.E4722K (on ENST00000367255 / NM_182961.4; = p.E4651K on NM_033071.3) | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.078); catalogued as rs35484093; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYT9 | c.625G>T p.D209Y | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV59618159, COSV59624341; called by muse, mutect2, varscan2
- TAF3 | c.2749_2751del p.K917del | In Frame Del (DEL) | VAF 26/136 reads (19%) | catalogued as rs759985447; called by pindel, varscan2
- TAOK2 | c.2729C>T p.P910L | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs778268053, COSV54235602; called by muse, mutect2, varscan2
- TPH2 | c.935C>T p.P312L | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756370445, COSV61591976; called by muse, mutect2, varscan2
- TRIM29 | c.260A>C p.D87A | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV59280228; called by muse, mutect2, varscan2
- TRPV5 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs199871524, COSV54685631; called by muse, mutect2, varscan2
- TTN | c.20C>T p.T7M | Missense Mutation (SNP) | VAF 14/51 reads (27%) | PolyPhen benign (0.028); catalogued as rs761344572, COSV60049091; called by muse, mutect2, varscan2
- UGGT2 | c.2685G>T p.L895F | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as COSV65074676; called by muse, mutect2, varscan2
- ZFHX4 | c.10598C>T p.A3533V | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.98); catalogued as rs750704900, COSV50500383, COSV51477866; called by muse, mutect2, varscan2
- ZIM2 | c.1204C>T p.R402C | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs779684815, COSV55625481; called by muse, mutect2, varscan2
- ZNF292 | c.4411C>T p.P1471S | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.541); catalogued as COSV100370406; called by muse, mutect2, varscan2
- ZNF462 | c.1924G>T p.E642* | Nonsense Mutation (SNP) | VAF 27/66 reads (41%) | catalogued as COSV52937850; called by muse, mutect2, varscan2
- AJUBA | c.977G>T p.R326L | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.045); called by muse, mutect2
- HIVEP3 | c.1601del p.P534Lfs*5 | Frame Shift Del (DEL) | VAF 5/29 reads (17%) | called by mutect2, pindel
- MRC1 | c.4004T>A p.L1335* | Nonsense Mutation (SNP) | VAF 135/619 reads (22%) | called by muse, mutect2, varscan2
- PGAM2 | c.325dup p.E109Gfs*29 | Frame Shift Ins (INS) | VAF 17/106 reads (16%) | called by mutect2, pindel, varscan2
- SLC25A19 | c.72_73del p.S25Wfs*23 | Frame Shift Del (DEL) | VAF 58/123 reads (47%) | called by pindel, varscan2
- SLC9C2 | c.2529del p.K843Nfs*2 | Frame Shift Del (DEL) | VAF 39/87 reads (45%) | called by mutect2, pindel, varscan2
- SOX9 | c.766_770dup p.P258Gfs*23 | Frame Shift Ins (INS) | VAF 63/124 reads (51%) | called by mutect2, pindel, varscan2
- ZCWPW1 | c.179del p.L60* | Frame Shift Del (DEL) | VAF 118/360 reads (33%) | called by mutect2, pindel, varscan2
- ABCA13 | c.2250C>T p.D750= | Silent (SNP) | VAF 58/183 reads (32%) | catalogued as COSV70028459; called by muse, mutect2, varscan2
- AC006059.2 | c.550C>T p.L184= | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as COSV59606873; called by muse, mutect2, varscan2
- ACTN3 | c.1926C>T p.N642= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as rs368786615; called by muse, mutect2, varscan2
- ADAT3 | c.894C>T p.Y298= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as rs1366360225, COSV60191069; called by muse, mutect2, varscan2
- AIFM3 | c.657C>T p.S219= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs772400232, COSV58999323; called by muse, mutect2, varscan2
- ASB7 | c.459G>A p.P153= | Silent (SNP) | VAF 20/37 reads (54%) | catalogued as rs946952467, COSV58403528; called by muse, mutect2, varscan2
- C10orf67 | c.312G>A p.T104= (on ENST00000323327; = p.T105= on NM_153714.3) | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as rs140159381; called by muse, mutect2, varscan2
- COL4A6 | c.4356C>G p.G1452= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV100564131; called by muse, mutect2, varscan2
- DMBT1 | c.390C>T p.S130= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs748067356, COSV57543580; called by muse, mutect2, varscan2
- EDEM2 | c.1362C>T p.F454= | Silent (SNP) | VAF 48/126 reads (38%) | catalogued as rs764625791, COSV63259473; called by muse, mutect2, varscan2
- EPHA10 | c.351C>T p.G117= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV60402798; called by muse, mutect2, varscan2
- GC | c.1383C>T p.Y461= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as COSV56737209; called by muse, mutect2, varscan2
- HAO1 | c.747A>G p.K249= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as COSV101113212; called by muse, mutect2, varscan2
- JARID2 | c.1497G>A p.P499= | Silent (SNP) | VAF 14/21 reads (67%) | catalogued as rs201664236, COSV59186527; called by muse, mutect2, varscan2
- KNDC1 | c.4620C>T p.N1540= | Silent (SNP) | VAF 40/78 reads (51%) | catalogued as rs751447204, COSV58836730; called by muse, mutect2, varscan2
- KRT73 | c.636C>T p.R212= | Silent (SNP) | VAF 26/122 reads (21%) | catalogued as rs760428547, COSV59839166; called by muse, mutect2, varscan2
- MEPE | c.480G>A p.A160= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as rs374913233; called by muse, mutect2, varscan2
- MEX3A | c.978C>T p.P326= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as rs561442043, COSV68479086; called by muse, mutect2, varscan2
- PCDHB3 | c.1341C>T p.N447= | Silent (SNP) | VAF 45/78 reads (58%) | catalogued as rs781985512, COSV50568853; called by muse, mutect2, varscan2
- PLEKHH2 | c.2424T>C p.P808= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV99174772; called by muse, mutect2, varscan2
- SCN3A | c.3249C>T p.Y1083= | Silent (SNP) | VAF 25/169 reads (15%) | catalogued as rs199850080, COSV51801600; ClinVar: likely benign; called by muse, mutect2, varscan2
- SEZ6L | c.1635G>A p.T545= | Silent (SNP) | VAF 20/33 reads (61%) | catalogued as rs368332411; called by muse, varscan2
- SIX6 | c.360G>A p.P120= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV59801655, COSV59802139; called by muse, mutect2, varscan2
- SLC35F3 | c.303G>A p.T101= (on ENST00000366617 / NM_001300845.1; = p.T170= on NM_173508.4) | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as rs563918632, COSV64019585; called by muse, mutect2, varscan2
- TENM3 | c.177C>T p.Y59= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as rs758643488, COSV69302654; called by muse, mutect2, varscan2
- THBS2 | c.2034C>T p.C678= | Silent (SNP) | VAF 23/95 reads (24%) | catalogued as rs1245785064, COSV64678758; called by muse, mutect2, varscan2
- TNPO3 | c.714G>A p.S238= | Silent (SNP) | VAF 38/84 reads (45%) | catalogued as rs1338377207, COSV55281258; ClinVar: likely benign; called by muse, mutect2, varscan2
- TRIM28 | c.2142C>T p.H714= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as rs756462692, COSV53400121; called by muse, mutect2, varscan2
- TTBK1 | c.147C>T p.Y49= | Silent (SNP) | VAF 20/31 reads (65%) | catalogued as COSV52487983; called by muse, mutect2, varscan2
- ZNF418 | c.708G>A p.G236= | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as COSV68675838; called by muse, mutect2, varscan2
- FAM183BP | n.959G>T | RNA (SNP) | VAF 49/118 reads (42%) | called by muse, mutect2, varscan2
- PPFIA1 | c.264+11588A>G | Intron (SNP) | VAF 13/81 reads (16%) | catalogued as COSV99557448; called by muse, mutect2, varscan2
- TTN | c.10361-4734G>T | Intron (SNP) | VAF 27/122 reads (22%) | catalogued as COSV60049081; called by muse, mutect2, varscan2
